FM case AD14225 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/a71d8632-131b-49fc-9ecd-5577fe1026d0

Male, 82.4 years: diagnosis not reported by GDC of the lung; specimen biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Tumor.
